Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6470, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6470-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Accession Number: [REDACTED]

Final Report

DIAGNOSIS:

1) TONSIL, RIGHT, EXCISION: INVASIVE, MODERATELY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 2.2 CM IN GREATEST DIMENSION, ALL RESECTION MARGINS NEGATIVE FOR TUMOR (SEE COMMENT).

2) SOFT TISSUE, RIGHT NECK, EXCISION: DENSE FIBROUS TISSUE AND FOREIGN BODY GIANT CELL REACTION, NEGATIVE FOR TUMOR.

3) "SOFT TISSUE," RIGHT NECK, LEVEL 1B, EXCISION: SALIVARY GLAND WITH NO SIGNIFICANT HISTOPATHOLOGIC CHANGE, NEGATIVE FOR TUMOR.

4) LYMPH NODE, RIGHT NECK, LEVEL 2-3, EXCISION: BENIGN FIBROADIPOSE TISSUE AND SKELETAL MUSCLE WITH SUTURE GRANULOMA; 11 LYMPH NODES, NEGATIVE FOR TUMOR.

5) SKIN, RIGHT NECK, EXCISION: SCAR AND SUTURE GRANULOMA, NEGATIVE FOR TUMOR.

6) LYMPH NODE, LEFT NECK, LEVEL 2-3, EXCISION: 13 LYMPH NODES, NEGATIVE FOR TUMOR.

7) TONSIL, LEFT, EXCISION: NEGATIVE FOR TUMOR.

8) TOOTH, 1, 31, 32, REMOVAL: MOLAR TEETH WITH NO SIGNIFICANT HISTOPATHOLOGIC CHANGE.

COMMENT: This corresponds to AJCC stage II (pT2, pN0).

Electronically signed by: [REDACTED]

CLINICAL DATA

Clinical Features/Dx: unspecified

Operator: [REDACTED]

Operation: unspecified

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: unspecified

[page 2 of 3]
GROSS DESCRIPTION:

1) SOURCE: Tonsil , Right

Received fresh is a specimen labeled, "right tonsil," consisting of a 2.8 x 2.0 x 1.1 cm tonsillectomy specimen. A 2.2 x 1.8 x 0.9 cm mass is identified on the mucosal surface of the specimen. The specimen is inked black. The specimen is serially sectioned and a portion of the specimen is obtained for future research studies. A portion of the specimen is submitted for frozen section analysis. The remainder of the specimen is submitted for permanent section.

Summary of sections: 1AFSC, 1/1; 1B-C, mass, 1B, 2/1, 1C, 3/1.

2) SOURCE: Right Neck adjacent to jugular vein

Received fresh is a specimen labeled, "soft tissue right neck adjacent to jugular vein," consisting of a 0.5 x 0.4 x 0.3 cm portion of soft tissue, which is entirely submitted for frozen section analysis.

Summary of sections: 2AFSC, 1/1.

3) SOURCE: Right neck level 1 B

Received fresh is a specimen labeled, "right neck level 1B," consisting of a 4.0 x 3.0 x 1.0 cm portion of yellow, soft, and lobulated adipose tissue. A search for lymph nodes is performed. No lymph nodes are identified through palpation. The specimen is serially sectioned to reveal tissue consistent with a salivary gland. The specimen is entirely submitted.

Summary of sections: 3A, 2/1; 3B, 1/1; 3C, 2/1; 3D, 1/1; 3E, 1/1.

4) SOURCE: Right neck level 2 + 3

Received fresh is a specimen labeled, "right neck level 2-3," consisting of two fragments of fibroconnective and adipose tissue, measuring 5.0 x 4.5 x 1.0 cm in aggregate. A search for lymph nodes is performed. The specimen is serially sectioned and entirely submitted.

Summary of sections: 4A, fragment of fibroconnective tissue, bisected, 1/1; 4B, three lymph nodes, 3/1; 4C, one lymph node, bisected, 2/1; 4D, three lymph nodes, 3/1; 4E-G, fragment of fibroconnective tissue, serially sectioned, 1/1 each.

5) SOURCE: Right neck scar

Received fresh is a specimen labeled, "right neck scar," consisting of a 7.0 x 0.7 x 0.4 cm portion of skin and subcutaneous tissue. A 6.0 cm scar is identified on the cutaneous surface of the specimen. The specimen is not oriented. The subcutaneous tissue is inked black. The specimen is serially sectioned and entirely submitted.

Summary of sections: 5A, tips, 2/1; 5B-C, scar, 5B, 8/1, 5C, 6/1.

6) SOURCE: Left neck level 2,3

Received fresh is a specimen labeled, "left neck level 2-3," consisting

[page 3 of 3]
of a 7.0 x 3.0 x 1.0 cm portion of fibroadipose tissue. A search for lymph nodes is performed. A representative portion of the specimen containing lymph nodes is submitted.

Summary of sections: 6A, four lymph nodes, 4/1; 6B, three lymph nodes, 3/1; 6C, portion of fibroconnective tissue, 1/1.

7) SOURCE: Tonsil , Left

Received fresh is a specimen labeled, "left tonsil," consisting of a tonsillectomy specimen, measuring 2.5 x 1.5 x 1.0 cm. The specimen reveals extensive cautery artifact. The specimen is inked black, serially sectioned and entirely submitted.

Summary of sections: 7A-B, tonsil, 2/1 each.

8) SOURCE: Teeth; 1,31,32

Received fresh is a specimen labeled, "teeth, 1, 31, 32," consisting of molar teeth with attached minimal amount of soft tissue, showing no significant histopathologic changes. The specimen is filed in the medicolegal file. No tissue is retained for permanent section. This is a gross diagnosis only.

Dictated by [REDACTED]
Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Tonsil , Right

FROZEN SECTION DIAGNOSIS: SQUAMOUS CELL CARCINOMA. [REDACTED]

2) SOURCE: Right Neck adjacent to jugular vein

FROZEN SECTION DIAGNOSIS: FIBROSIS AND FOREIGN BODY GIANT CELL REACTION; BENIGN. [REDACTED]

Electronically signed by: [REDACTED]
Pathologist

SNOMED: T-C5100,M-80103,

[REDACTED] Release of Information [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file d02b0622-2beb-45e7-9c57-56295a45542b (TCGA-CR-6470.BE017BB8-F71A-4C46-8574-1D2F62EEB6B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).